Surgical pathology report (de-identified scan), TCGA case TCGA-06-6695, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-6695-01A (Primary Tumor).

[page 1 of 4]
TCGA-06-6695

Surgical Pathology Report

=====

CLINICAL HISTORY

Right temporoparietal lesion.

OPERATIVE DIAGNOSES

Operation/Specimen: A: Right brain tumor, biopsy

B: Right brain tumor, biopsy

PATHOLOGICAL DIAGNOSIS:

A. and B. Brain, right cerebral tumor, biopsy: Glioblastoma (WHO Grade IV)
(see comment).

COMMENT

Permanent sections confirm the frozen section diagnosis. Sections show a glioma demonstrating angulated and spindle-shaped nuclei, frequent mitotic

figures, microvascular proliferation and sheet necrosis. The tumor cells are reticulin negative.

Immunohistochemistry: The tumor is diffusely GFAP positive. p53 highlights

scattered cells. The Ki-67 labeling index is up to 25%.

Positive and negative controls show appropriate immunoreactivity.

Results of molecular studies will be reported below in procedure addenda.

=====

PROCEDURES/ADDENDA

PCR for EGFR variant III mutation

Date Ordered: [REDACTED]

Date Reported: [REDACTED]

[page 2 of 4]
Interpretation

NEGATIVE - No evidence of EGFRvIII mutation is detected

Results-Comments

TEST DESCRIPTION: Testing performed on RNA extracted from tissue paraffin block

The epidermal growth factor receptor (EGFR) is an attractive molecular target in glioblastoma because it is amplified, overexpressed, and/or mutated in up to 40% to 50% of patients. Epidermal growth factor receptor variant III

(EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is

commonly expressed in glioblastoma. Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct

subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been

shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor

suppressor protein PTEN is intact. RNA is extracted from formalin fixed,

paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is

then amplified using standard PCR technique for DNA templates. PCR products

are detected by gel electrophoresis. The limit of detection of this assay has

been determined to be approximately 5 mutant cells in 100 normal cells.

FDA Comment: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] laboratory as required by CLIA [REDACTED] regulations. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

the context of established procedures and/or diagnostic criteria.

Interpretation

[page 3 of 4]
POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block
H slide was examined and no microdissection was
needed.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT
promoter
have been shown to benefit from therapy with alkylating agents.
Assessment of
MGMT promoter methylation status involves bisulfite treatment of DNA
followed
by real-time PCR amplification (MethyLight) of methylated and
unmethylated DNA
sequences. The analytic sensitivity of this assay was determined by
serial
dilution of methylated positive control DNA into unmethylated DNA, and
was
assessed to be 1% of methylated DNA in the background of unmethylated
DNA.
Factors such as the presence of >50% non-neoplastic cells in the
sample, or
extensive tissue necrosis, may preclude the detection of methylated
MGMT
promoter sequences.

FDA COMMENT: The above data are not to be construed as the results
from a
stand alone diagnostic test. This test was developed and its
performance
characteristics determined by the [REDACTED] laboratory as
required by CLIA [REDACTED] regulations. It has not been cleared or approved
for
specific uses by the U.S. Food and Drug Administration (FDA). The FDA
has
determined that such clearance or approval is not necessary. These
results are
provided for informational purposes only, and should be interpreted
only in
the context of established procedures and/or diagnostic criteria.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A. Right brain tumor, biopsy: High grade glioma (1 block) [REDACTED]

[REDACTED] Frozen section and smears performed at [REDACTED] and
results
reported to the Physician of Record.

[REDACTED]

[page 4 of 4]
GROSS DESCRIPTION

A. Right brain tumor, biopsy:

CONTAINER LABEL: right brain tumor.

FIXATIVE: Formalin. NO. PIECES: 5. SIZE/VOL: 3-9 mm. CASSETTES: 2,

B. Right brain tumor, biopsy:

CONTAINER LABEL: right brain tumor.

FIXATIVE: Formalin. NO. PIECES: 3. SIZE/VOL: 6-7 mm. CASSETTES: 1,

ICD-9(s):

191.9 225.0

Histo Data

Part A: Right brain tumor, biopsy

Taken:

Received:

Stain/cnt

Block

Ordered

Comment

FS H/E x 1

1

H/E x 1

1

TPS H/E x 1

1

H/E x 1

2

Part B: Right brain tumor, biopsy

Taken:

Received:

Stain/cnt

Block

Ordered

Comment

EGFR VIII-curls x 1

1

mGFAP-DA x 1

1

H/E x 1

1

MGMT-curls x 1

1

MIB1-DA x 1

1

P53DO7 x 1

1

Retic x 1

1

*** End of Report ***

Source: NCI Genomic Data Commons file 586ddab2-183e-4f0a-8a4d-09aceb959386 (TCGA-06-6695.3E41FBB4-4032-4931-B91C-ADE80781EA25.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).